Somatic mutation profile of tumor specimen MP2PRT-PATKIA-TMP1-A (aliquot MP2PRT-PATKIA-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATKIA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,449 days).
Specimen MP2PRT-PATKIA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5f715c5-2272-4452-8f29-302ef98cbe8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKIA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKIA-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c62afd-7165-4bfe-8ad6-bea92cd51439

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 30/197 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 42/192 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RYR1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs1568440962, CD137530, COSV99051977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH2 | c.9682C>T p.R3228W | Missense Mutation (SNP) | VAF 125/381 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs532022925; called by muse, mutect2, varscan2
- FDCSP | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.458); catalogued as rs764407142, COSV58764695; called by muse, mutect2, varscan2
- GREB1L | c.5192G>A p.R1731H | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1193849295; called by muse, mutect2, varscan2
- SUN2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs555329396, COSV53303121; called by muse, mutect2, varscan2
- AFF2 | c.3454G>A p.D1152N | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- COG6 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HOXC6 | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 127/284 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IAPP | c.146del p.L49* | Frame Shift Del (DEL) | VAF 68/279 reads (24%) | called by mutect2, pindel, varscan2
- MAST4 | c.6553G>A p.A2185T (on ENST00000403625 / NM_001164664.2; = p.A1996T on NM_015183.3) | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); called by muse, mutect2
- PCDH15 | c.4931C>T p.T1644I | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STON2 | c.1071_1072insGG p.P358Gfs*4 (on ENST00000649389 / NM_001366849.2; = p.P301Gfs*4 on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 93/367 reads (25%) | called by mutect2, varscan2
- STON2 | c.1070delinsGGG p.T357Rfs*5 (on ENST00000649389 / NM_001366849.2; = p.T300Rfs*5 on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 107/410 reads (26%) | called by mutect2*, pindel, varscan2*
- GOLGA6L2 | c.1836C>T p.D612= | Silent (SNP) | VAF 109/718 reads (15%) | catalogued as rs574416569, COSV61486012; called by muse, mutect2, varscan2
- LRRC30 | c.399G>A p.P133= | Silent (SNP) | VAF 60/445 reads (13%) | called by muse, mutect2, varscan2
- SCGB1D1 | c.93C>A p.I31= | Silent (SNP) | VAF 39/369 reads (11%) | called by muse, mutect2, varscan2
